TCGA case TCGA-VR-A8EO — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/705f9841-988a-488a-8cdd-3e00bc731e76

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Brazil; Age at index: 49 years; Vital status: Alive; Country of birth: Brazil.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 49.6 years (18,123 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC clinical T: T3; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIA; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 785 days (2.1 years); Cancer detection method: Symptomatic; Esophageal columnar dysplasia degree: Negative/ No Dysplasia; Esophageal columnar metaplasia present: No; Goblet cells columnar mucosa present: No; Sites of involvement: Esophagus, Middle Third / Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 8.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 104 days; Days to treatment end: 145 days; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Chemotherapy, preoperative; adjuvant Pharmaceutical Therapy, NOS; Radiation Therapy, NOS, preoperative.

Follow-up (6 entries)
- Days to follow up: 509 days (1.4 years); Disease response: Tumor Free.
- Days to follow up: 572 days (1.6 years); Disease response: Tumor Free.
- Days to follow up: 785 days (2.1 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 1.
- Barretts esophagus goblet cells present: No; Timepoint: Prior to Diagnosis.
- Follow-up contact recording only the day: day 690.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 63 kg; Height: 179 cm; BMI: 19.7.
- Timepoint category: Prior to Diagnosis; Comorbidities: GERD; Reflux treatment type: No Treatment; Risk factors: GERD.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 5; Alcohol days per week: 5.
- Exposure type: Tobacco.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VR-A8EO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 160 mg.
  Slide TCGA-VR-A8EO-01A-01-TSA: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 35; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 3.
- Sample TCGA-VR-A8EO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VR-A8EO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Cancer procurement state province: Sao Paulo; Cancer procurement city: Barretos; History neoadjuvant treatment: No; Tumor status: Tumor free; Alcohol consumption frequency: 5; History reflux disease indicator: Yes; History hpylori infection indicator: Never; History barretts esophageal indicator: No; New tumor event diagnosis indicator: No.
- Primary pathology: Esophageal tumor location centered: Distal; Histologic diagnosis: Esophagus Squamous Cell Carcinoma; Esoph non CA degree of dysplasia: Negative/no dysplasia; Method initial path diagnosis: Endoscopic Biopsy; Lymph node sprd radiograph evidence: No; Lymph nodes examined: Yes; Patient to undergo surgery: Surgery already performed.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Mid; Esophageal tumor location involved: Distal.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 785 days; disease-specific survival: no event (censored), 785 days; disease-free interval: no event (censored), 785 days; progression-free interval: no event (censored), 785 days.
